Somatic mutation profile of tumor specimen MMRF_2388_1_BM_CD138pos (aliquot MMRF_2388_1_BM_CD138pos_T1_KHS5U_K14019) from MMRF case MMRF_2388, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,064 days).
Specimen MMRF_2388_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15032f6c-311e-4943-9485-9b7a6fb77e32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2388_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2388_1_PB_Whole_C1_KHS5U_K14018; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ce4757a-4a31-45de-96ec-79d4976c2ed2

The open-access MAF lists 151 somatic variants for this specimen: 58 protein-altering or splice-affecting, 24 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 38, Silent 24, Intron 17, 5'Flank 6, RNA 4, Frame Shift Del 3, 3'Flank 2, Nonsense Mutation 2, 5'UTR 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 29/271 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 56/277 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATM | c.3082C>G p.L1028V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1263930458, COSV99588630; ClinVar: uncertain significance; called by muse, mutect2
- CAPN9 | c.355del p.Q119Rfs*27 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs777676239; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs746903524, COSV62571997; called by muse, mutect2, varscan2
- CDON | c.3515C>T p.P1172L | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs370469702; called by muse, mutect2
- CNTNAP2 | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62194222; called by muse, mutect2
- COL5A1 | c.5495G>A p.G1832E | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554727410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPN2 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs371925650; called by muse, mutect2, varscan2
- CTSF | c.722-4G>T | Splice Region (SNP) | VAF 38/200 reads (19%) | catalogued as rs780325681; called by muse, mutect2, varscan2
- CYB5D2 | c.415G>C p.G139R | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56800426; called by muse, mutect2, varscan2
- EFCAB6 | c.3625G>A p.V1209I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs533490129, COSV53076235; called by muse, mutect2, varscan2
- EHBP1L1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567467176; called by muse, mutect2, varscan2
- FGD6 | c.3997G>C p.D1333H | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59691298; called by muse, mutect2, varscan2
- FNBP1L | c.1384C>T p.R462* (on ENST00000271234 / NM_001164473.2; = p.R404* on NM_017737.5) | Nonsense Mutation (SNP) | VAF 19/156 reads (12%) | catalogued as rs777402212, COSV99554154; called by muse, mutect2, varscan2
- GLB1L3 | c.899T>C p.M300T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as rs996468222, COSV66282835; called by muse, mutect2, varscan2
- GPSM2 | c.557+2T>C p.X186_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | catalogued as rs758733242; called by muse, mutect2, varscan2
- HAVCR1 | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV59401820; called by muse, mutect2, varscan2
- IGHV3-73 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs776238581; called by muse, varscan2
- IGKV1D-43 | c.133T>G p.C45G | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1228726332; called by muse, mutect2, varscan2
- IZUMO1 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 87/444 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.149); catalogued as COSV99710993; called by muse, mutect2, varscan2
- LRP1 | c.12347A>G p.H4116R | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1393766278; called by muse, mutect2
- N4BP2 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV54701484; called by muse, mutect2, varscan2
- NPY2R | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1393892927, COSV61528415; called by muse, mutect2, varscan2
- PDE3A | c.3107C>T p.T1036I | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.65); catalogued as rs1486423491; called by muse, mutect2, varscan2
- POLB | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs377121458; called by muse, mutect2, varscan2
- PPP2R2C | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV59446765; called by muse, mutect2
- PTPN21 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs749109098, COSV60846625; called by muse, mutect2, varscan2
- SDK2 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs145662298; called by muse, mutect2, varscan2
- TBX3 | c.2135C>T p.A712V (on ENST00000257566 / NM_016569.4; = p.A692V on NM_005996.4) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs750109853; called by muse, mutect2, varscan2
- TRPS1 | c.3842A>G p.E1281G (on ENST00000220888 / NM_001330599.2; = p.E1294G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1357601065; called by muse, mutect2, varscan2
- TSSK1B | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.109); catalogued as rs1332155285; called by muse, mutect2
- ZDHHC21 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749477638; called by muse, mutect2, varscan2
- ZMYND15 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs778047503, COSV99351848; called by muse, mutect2, varscan2
- AGBL3 | c.2511G>C p.K837N | Missense Mutation (SNP) | VAF 101/316 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARNTL | c.1577G>T p.S526I (on ENST00000403290 / NM_001297719.2; = p.S525I on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- BNC1 | c.1448A>G p.K483R | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BUB1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C5 | c.4344del p.Q1448Hfs*17 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.1852G>A p.G618S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2
- CTBP2 | c.104del p.L35Rfs*17 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- FSIP2 | c.16429A>C p.T5477P | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- HHIP | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 37/295 reads (13%) | called by muse, mutect2, varscan2
- IGLV2-8 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, varscan2
- KCNC2 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.41); called by muse, varscan2
- KIF26A | c.1385A>T p.D462V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAFA | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOTCH3 | c.6782C>A p.P2261H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OSBPL1A | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPP2R2C | c.1273A>T p.N425Y | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2
- RGS3 | c.3116G>A p.R1039K (on ENST00000350696 / NM_001282923.2; = p.R758K on NM_130795.4) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- RYR2 | c.11041A>C p.K3681Q | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.858); called by muse, mutect2
- SOCS7 | c.1834A>T p.I612F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- U2SURP | c.1545G>C p.M515I | Missense Mutation (SNP) | VAF 95/511 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- WDR1 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ZBBX | c.1922C>A p.S641Y | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZNF568 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- ZSWIM3 | c.2000A>G p.D667G | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS10 | c.3081G>A p.S1027= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs781916006; called by muse, mutect2
- ADAMTS13 | c.2721C>T p.S907= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs587726656; called by muse, mutect2, varscan2
- ADRA1D | c.1038G>A p.A346= | Silent (SNP) | VAF 99/274 reads (36%) | catalogued as rs867469613, COSV101063008; called by muse, varscan2
- CD27 | c.34C>T p.L12= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- CELSR2 | c.8058G>A p.E2686= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs1243838260; called by muse, mutect2
- CEP290 | c.6517T>C p.L2173= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2
- CFAP43 | c.3120C>T p.R1040= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as rs1327620621, COSV53377040; called by muse, mutect2
- CLDN6 | c.433C>A p.R145= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1455379665, COSV58511108; called by muse, mutect2, varscan2
- CNTNAP3B | c.702G>A p.L234= | Silent (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- CSMD1 | c.747C>A p.V249= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs762380961, COSV101226615; called by muse, mutect2, varscan2
- DSCAM | c.2937G>A p.A979= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1031920480, COSV68027706; called by muse, mutect2
- DYNC2H1 | c.11169C>T p.I3723= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as rs1372823778, COSV62104731; called by muse, mutect2, varscan2
- GABBR1 | c.2703C>A p.I901= | Silent (SNP) | VAF 186/492 reads (38%) | catalogued as COSV63543123; called by mutect2, varscan2
- IGHV3-73 | c.60G>A p.E20= | Silent (SNP) | VAF 54/172 reads (31%) | catalogued as rs566209321; called by muse, varscan2
- IGLV3-1 | c.216G>A p.R72= | Silent (SNP) | VAF 60/86 reads (70%) | catalogued as rs374319890; called by muse, varscan2
- IPMK | c.30G>C p.R10= | Silent (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- ITPRID2 | c.1425G>A p.T475= | Silent (SNP) | VAF 56/135 reads (41%) | catalogued as rs771071833, COSV57470879; called by muse, mutect2, varscan2
- MRM1 | c.9G>A p.L3= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs1159042992; called by muse, mutect2, varscan2
- MROH2A | c.4563C>T p.L1521= | Silent (SNP) | VAF 70/156 reads (45%) | called by muse, mutect2, varscan2
- MRPL47 | c.252A>C p.A84= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- PCDH15 | c.2799G>A p.G933= | Silent (SNP) | VAF 76/291 reads (26%) | catalogued as rs139853291, COSV57287455; called by muse, mutect2, varscan2
- SLC16A14 | c.1050C>T p.N350= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as rs1335479181, COSV54617336; called by muse, mutect2, varscan2
- SOX8 | c.966G>A p.P322= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs754519733; called by muse, mutect2, varscan2
- TMEM200C | c.390G>A p.A130= | Silent (SNP) | VAF 109/252 reads (43%) | called by muse, mutect2, varscan2
- ABHD2 | c.*644C>G | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2
- AC093155.3 | c.767-1450G>A | Intron (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- ACACA | c.*1012C>T | 3'UTR (SNP) | VAF 56/135 reads (41%) | called by muse, mutect2, varscan2
- AFF2 | c.*3349C>T | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- AKAP9 | chr7:91941036 C>T | 5'Flank (SNP) | VAF 328/563 reads (58%) | called by muse, mutect2, varscan2
- AL031282.1 | n.520_523del | RNA (DEL) | VAF 49/317 reads (15%) | called by mutect2, pindel, varscan2
- AMMECR1L | c.*120A>T | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1892-916G>C | Intron (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.*1283T>A | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- BRDT | chr1:92014422 del T | 3'Flank (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- C4B | chr6:32012192 T>A | 5'Flank (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- CACNA1C | c.*401G>T | 3'UTR (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- CENPW | c.-62G>A | 5'UTR (SNP) | VAF 35/175 reads (20%) | called by muse, mutect2, varscan2
- CSNK1G1 | c.*1644C>T | 3'UTR (SNP) | VAF 19/75 reads (25%) | catalogued as rs1196484186; called by muse, mutect2, varscan2
- EN2 | c.*32G>A | 3'UTR (SNP) | VAF 84/362 reads (23%) | catalogued as rs992170679; called by muse, mutect2, varscan2
- ENO2 | c.-12-12C>T | Intron (SNP) | VAF 65/463 reads (14%) | called by muse, mutect2, varscan2
- EPS15 | c.*153_*171delinsTCTTCATTACAGATTCGTC | 3'UTR (ONP) | VAF 4/47 reads (9%) | called by pindel, varscan2*
- FAM120A | c.1734+780A>G | Intron (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- FAM131B | c.-57+847C>T | Intron (SNP) | VAF 35/134 reads (26%) | catalogued as rs952882944; called by muse, mutect2, varscan2
- FAM220BP | n.583G>A | RNA (SNP) | VAF 52/334 reads (16%) | called by muse, mutect2, varscan2
- FAM71F2 | c.*513del | 3'UTR (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- FERMT2 | c.*302G>A | 3'UTR (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- FFAR4 | c.*1212G>A | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- FOXN1 | c.*1385G>A | 3'UTR (SNP) | VAF 33/166 reads (20%) | called by muse, mutect2, varscan2
- GALNT5 | c.*586T>C | 3'UTR (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- GPX8 | c.*434G>A | 3'UTR (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- GSTM4 | c.113-106G>T | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- HSPA2 | c.*45_*47del | 3'UTR (DEL) | VAF 27/214 reads (13%) | catalogued as rs1021437912; called by mutect2, pindel, varscan2
- KCNA4 | c.*135C>G | 3'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- KCNAB2 | c.372-88G>A | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as rs916333163, COSV51236670; called by muse, mutect2, varscan2
- KIAA1549L | c.*3601dup | 3'UTR (INS) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- KRBA2 | c.*9258_*9261del | 3'UTR (DEL) | VAF 58/164 reads (35%) | called by mutect2, pindel, varscan2
- LMBR1 | c.*1178C>T | 3'UTR (SNP) | VAF 15/107 reads (14%) | catalogued as rs1366666900; called by muse, mutect2, varscan2
- MAP4K5 | c.1015+131A>G | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- MIR5195 | chr14:106851318 G>A | 5'Flank (SNP) | VAF 98/200 reads (49%) | catalogued as rs184165450; called by muse, varscan2
- MTHFD2L | chr4:74157971 G>A | 5'Flank (SNP) | VAF 119/300 reads (40%) | catalogued as rs1173580918; called by muse, mutect2, varscan2
- MYH16 | n.3479C>T | RNA (SNP) | VAF 24/34 reads (71%) | catalogued as rs569021018; called by muse, varscan2
- MYT1L | c.*540A>G | 3'UTR (SNP) | VAF 92/324 reads (28%) | called by muse, varscan2
- NHLRC3 | c.*1100T>A | 3'UTR (SNP) | VAF 68/91 reads (75%) | called by muse, mutect2, varscan2
- NIPSNAP1 | chr22:29581270 del CTGCGACCTTGG | 5'Flank (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- NRN1 | c.*346G>A | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- NTS | c.136-152T>A | Intron (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- PDXK | c.*56T>C | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- PRKCE | c.*618A>T | 3'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.9-26G>A | Intron (SNP) | VAF 30/91 reads (33%) | catalogued as rs751364457; called by muse, mutect2, varscan2
- PYM1 | c.*226A>T | 3'UTR (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- RADX | c.*420G>C | 3'UTR (SNP) | VAF 40/59 reads (68%) | called by muse, mutect2, varscan2
- RASSF1 | c.*440_*452del | 3'UTR (DEL) | VAF 65/158 reads (41%) | called by mutect2, pindel, varscan2
- RBM24 | c.348-1700A>C | Intron (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- RNF217 | c.*3380del | 3'UTR (DEL) | VAF 27/63 reads (43%) | catalogued as rs1209607587; called by mutect2, varscan2
- RUNX1T1 | c.*3582C>A | 3'UTR (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+4187A>T | Intron (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- SAR1B | c.*2858G>A | 3'UTR (SNP) | VAF 37/57 reads (65%) | called by muse, mutect2, varscan2
- SCN9A | c.*139C>T | 3'UTR (SNP) | VAF 24/104 reads (23%) | catalogued as rs200380193; called by muse, mutect2, varscan2
- SENP7 | c.1837+498C>G | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- SERF1B | c.116+3417A>G | Intron (SNP) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- SLC52A3 | c.*473G>C | 3'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- SLC6A10P | n.1224G>A | RNA (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- SLC6A7 | c.*223G>T | 3'UTR (SNP) | VAF 136/198 reads (69%) | called by muse, varscan2
- SRRM4 | c.*4786A>G | 3'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- SUGT1P3 | n.215-1375C>G | Intron (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- TEAD1 | c.*1125G>T | 3'UTR (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- TRAPPC6B | c.-36G>C | 5'UTR (SNP) | VAF 106/416 reads (25%) | catalogued as COSV100351348; called by muse, mutect2, varscan2
- TRIM67 | chr1:231220129 C>T | 3'Flank (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*345G>C | 3'UTR (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- UTRN | c.*1703_*1726del | 3'UTR (DEL) | VAF 18/102 reads (18%) | called by mutect2, pindel
- ZNF687 | chr1:151279959 C>A | 5'Flank (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- ZNF852 | c.142+39C>T | Intron (SNP) | VAF 14/89 reads (16%) | catalogued as rs759031347; called by muse, mutect2, varscan2
- ZNF852 | c.142+38G>T | Intron (SNP) | VAF 14/88 reads (16%) | called by mutect2, varscan2
